Gene-level copy-number profile of tumor specimen TCGA-VS-A9UA-01A from TCGA case TCGA-VS-A9UA, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 60.8 years (22,221 days).
Specimen TCGA-VS-A9UA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.8b115d16-51ff-4bb3-8aa3-d6a95b92da8b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VS-A9UA-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d2715391-2440-4704-9d37-27c76565f80e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,233; copy number 2: 45,132; copy number 3: 7,541; copy number 4: 3,808; copy number 5: 106.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VS-A9UA-01A-11D-A42N-01): tumor purity 0.62, ploidy 2.2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 106 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:109,988,097–110,129,136, 1 gene, copy number 5 (within-gene range 4–5): AL390755.1.
- chr13:110,053,285–114,337,626, 105 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,231. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
